Somatic mutation profile of tumor specimen MP2PRT-PAPIPG-TMP1-A (aliquot MP2PRT-PAPIPG-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPIPG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,576 days).
Specimen MP2PRT-PAPIPG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd0ea10a-10ae-4597-b24a-e7313530dab3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPIPG-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPIPG-NM1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc0ae445-5ee4-45d1-a7a4-b4777ed6447b

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, 5'UTR 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCYAP1R1 | c.1294C>T p.H432Y | Missense Mutation (SNP) | VAF 130/320 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs151305519; called by muse, varscan2
- KCTD16 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 166/377 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as rs1434066147, COSV72578389; called by muse, mutect2, varscan2
- OBSL1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 151/352 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs546549598; called by muse, mutect2, varscan2
- ZFHX4 | c.7132G>T p.A2378S | Missense Mutation (SNP) | VAF 13/408 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV50664975; called by muse, mutect2
- FSIP2 | c.18707A>T p.K6236M | Missense Mutation (SNP) | VAF 125/256 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ICMT | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- IRF9 | c.421_422insGTCTAAG p.E141Gfs*27 | Frame Shift Ins (INS) | VAF 106/255 reads (42%) | called by mutect2, pindel, varscan2
- LIMCH1 | c.3083T>G p.I1028S | Missense Mutation (SNP) | VAF 81/290 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- PLEKHA1 | c.912C>T p.P304= | Silent (SNP) | VAF 18/326 reads (6%) | catalogued as rs138394797, COSV64568917, COSV64569570; called by muse, mutect2
- PXDNL | c.630C>T p.C210= | Silent (SNP) | VAF 132/276 reads (48%) | catalogued as rs567458796; called by muse, mutect2, varscan2
- TJP1 | c.3438C>T p.Y1146= | Silent (SNP) | VAF 190/423 reads (45%) | catalogued as rs377315401; called by muse, mutect2, varscan2
- C7orf25 | c.-149G>A | 5'UTR (SNP) | VAF 14/413 reads (3%) | called by muse, mutect2
- KCNQ1 | c.1514+36148G>C | Intron (SNP) | VAF 102/248 reads (41%) | called by muse, mutect2, varscan2
